Somatic mutation profile of tumor specimen MP2PRT-PATLRA-TMP1-A (aliquot MP2PRT-PATLRA-TMP1-A-1-0-D-A817-36) from MP2PRT case MP2PRT-PATLRA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.1 years (1,496 days).
Specimen MP2PRT-PATLRA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 724869b2-4e92-48f1-971b-734faee4be5c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATLRA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATLRA-NB1-A-1-0-D-A817-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8dab8403-a6f3-49c7-a2ea-baa237147a48

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 12, Silent 5, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 34/179 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.5060C>T p.S1687F | Missense Mutation (SNP) | VAF 173/444 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.355); catalogued as CM123180, COSV52119465; called by muse, mutect2, varscan2
- CTNNA2 | c.1012G>A p.V338M | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs768529296, COSV63553496, COSV63606300; called by muse, mutect2, varscan2
- CYP11B2 | c.1206G>T p.L402F | Missense Mutation (SNP) | VAF 106/247 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); catalogued as COSV100010603; called by muse, mutect2, varscan2
- ERBB4 | c.2615A>T p.E872V | Missense Mutation (SNP) | VAF 90/261 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV61530171; called by muse, mutect2, varscan2
- GRM4 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 108/454 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs773610073, COSV100945900; called by muse, mutect2, varscan2
- KIAA1549L | c.4966C>T p.R1656* (on ENST00000321505; = p.R1953* on NM_012194.3) | Nonsense Mutation (SNP) | VAF 26/314 reads (8%) | catalogued as rs779349085; called by muse, mutect2
- NRG1 | c.1349C>T p.S450L (on ENST00000405005 / NM_013964.5; = p.S455L on NM_013956.5) | Missense Mutation (SNP) | VAF 172/375 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs767284530, COSV55153288; called by muse, mutect2, varscan2
- NUTM2F | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 34/423 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs369329276, COSV53555156; called by muse, mutect2
- PIP5KL1 | c.773G>A p.R258Q (on ENST00000388747 / NM_001135219.2; = p.R55Q on NM_173492.1) | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs758224613, COSV55944279; called by muse, mutect2, varscan2
- PLA2R1 | c.2288A>G p.D763G | Missense Mutation (SNP) | VAF 68/180 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs750401152; called by muse, mutect2, varscan2
- TARM1 | c.409C>T p.R137* (on ENST00000616041 / NM_001330650.1; = p.R129* on NM_001135686.3) | Nonsense Mutation (SNP) | VAF 21/352 reads (6%) | catalogued as rs754706900; called by muse, mutect2
- CDH19 | c.145C>T p.Q49* | Nonsense Mutation (SNP) | VAF 104/312 reads (33%) | called by muse, mutect2, varscan2
- DACH2 | c.1346C>G p.A449G | Missense Mutation (SNP) | VAF 79/616 reads (13%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- FAM200A | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 123/275 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- AMY2A | c.816G>A p.K272= | Silent (SNP) | VAF 60/642 reads (9%) | catalogued as rs1397361788; called by muse, mutect2
- MECP2 | c.1329C>T p.A443= | Silent (SNP) | VAF 42/1014 reads (4%) | catalogued as rs782706777; ClinVar: benign; called by muse, mutect2
- METTL27 | c.384G>A p.P128= | Silent (SNP) | VAF 15/373 reads (4%) | catalogued as rs185546989; called by muse, mutect2
- RIMBP2 | c.1719C>T p.S573= | Silent (SNP) | VAF 41/607 reads (7%) | catalogued as rs181923151, COSV99899743; called by muse, mutect2
- SLC44A3 | c.171C>T p.A57= (on ENST00000271227 / NM_001114106.3; = p.A9= on NM_152369.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 122/318 reads (38%) | catalogued as rs149788729; called by muse, mutect2, varscan2
